Somatic mutation profile of tumor specimen TARGET-30-PATHYK-01A (aliquot TARGET-30-PATHYK-01A-01D) from TARGET case TARGET-30-PATHYK, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.7 years (256 days).
Specimen TARGET-30-PATHYK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2644b57e-e9b5-4940-aef3-d09b83b0bf8a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATHYK-10A (Blood Derived Normal), aliquot TARGET-30-PATHYK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db89281d-331d-4331-9681-6f52c663a38e

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7189+2T>C p.X2397_splice (on ENST00000358273 / NM_001042492.3; = p.X2376_splice on NM_000267.3) | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as CS1512944, COSV62209232, COSV62227280; called by muse, mutect2, varscan2
- PTPRT | c.*8055G>C | 3'UTR (SNP) | VAF 35/112 reads (31%) | catalogued as COSV62035680; called by muse, mutect2, varscan2
